Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00A, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00A-01A (Primary Tumor).

Sample ID #

Diagnosis:

Right hemicolectomy preparation with tumor-free resection margins and an ulcerated, moderately differentiated adenocarcinoma of the ascending colon, with infiltration of the perimuscular fatty tissue and without local lymph node metastases (G2, pT3 L0 V0 R0 pN0 0/34).

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: ascending colon C18.2 W 3/29/11

TIIPAA Discrepancy		☒
Reviewed Initials:	RMT	W

Source: NCI Genomic Data Commons file eb62a943-d9e7-4d3c-8092-d4306cd35093 (TCGA-AA-A00A.8159A57E-D8E0-406E-9DAC-3E26E8EB1BA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).